Somatic mutation profile of tumor specimen 0DG5AF from CCDI case PBBRPZ, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Vital status: Alive; Primary diagnosis: Medullary carcinoma, NOS; Tissue or organ of origin: Kidney, NOS; Age at diagnosis: 15.1 years (5,522 days).
Specimen 0DG5AF: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 67130502-86ba-4579-a72e-a0872f61fddf.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DG5A9 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9c188c6d-1a99-43be-bc3b-d9140dde2984

The open-access MAF lists 17 somatic variants for this specimen: 12 protein-altering or splice-affecting, 2 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 11, Silent 2, Intron 2, Nonsense Mutation 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADAMTSL1 | c.4027G>A p.V1343M | Missense Mutation (SNP) | VAF 79/957 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.979); catalogued as rs374073733; called by muse, mutect2
- CCL23 | c.242C>T p.P81L | Missense Mutation (SNP) | VAF 74/703 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.91); catalogued as rs142522197; called by muse, mutect2, varscan2
- KIRREL3 | c.364G>A p.D122N | Missense Mutation (SNP) | VAF 50/404 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs767674597, COSV73104760; called by muse, mutect2, varscan2
- RGS7 | c.130C>T p.R44C | Missense Mutation (SNP) | VAF 72/1011 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs755007339, COSV58530073, COSV58530443; called by muse, mutect2
- WDSUB1 | c.422C>T p.S141F | Missense Mutation (SNP) | VAF 48/682 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV63067301; called by muse, mutect2
- ZNF488 | c.848C>G p.S283C | Missense Mutation (SNP) | VAF 38/388 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1188213612; called by muse, mutect2
- AFF4 | c.1774T>A p.L592M | Missense Mutation (SNP) | VAF 62/746 reads (8%) | SIFT tolerated (0.13); PolyPhen benign (0.001); called by muse, mutect2
- OTUD5 | c.503G>A p.R168H | Missense Mutation (SNP) | VAF 24/354 reads (7%) | SIFT tolerated (0.14); PolyPhen benign (0.289); called by muse, mutect2
- SNX18 | c.826T>A p.F276I | Missense Mutation (SNP) | VAF 21/394 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- SRPK2 | c.1658T>C p.I553T | Missense Mutation (SNP) | VAF 112/1084 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.455); called by muse, mutect2
- ZHX1 | c.1874T>G p.L625* | Nonsense Mutation (SNP) | VAF 118/1306 reads (9%) | called by muse, mutect2
- ZNF354B | c.1326A>T p.E442D | Missense Mutation (SNP) | VAF 51/735 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.009); called by muse, mutect2
- PTPRJ | c.3933C>T p.Y1311= | Silent (SNP) | VAF 79/957 reads (8%) | called by muse, mutect2
- TBC1D3I | c.1596G>A p.G532= | Silent (SNP) | VAF 8/206 reads (4%) | catalogued as rs1171843607, rs1311658975; called by muse, mutect2
- ETS2 | c.-150-14C>T | Intron (SNP) | VAF 25/329 reads (8%) | called by muse, mutect2
- OR5L1 | c.*56C>T | 3'UTR (SNP) | VAF 21/237 reads (9%) | catalogued as rs1012855448, COSV61733094; called by muse, mutect2
- PIK3R6 | c.189+56T>C | Intron (SNP) | VAF 14/106 reads (13%) | catalogued as rs750071196; called by muse, mutect2, varscan2
